Somatic mutation profile of tumor specimen TARGET-20-PASDUD-09A (aliquot TARGET-20-PASDUD-09A-02D) from TARGET case TARGET-20-PASDUD, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.5 years (4,184 days).
Specimen TARGET-20-PASDUD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cabc549-baae-4628-8f42-ed6a11391783.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASDUD-14A (Bone Marrow Normal), aliquot TARGET-20-PASDUD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5966a737-53b0-4468-8942-b8ded48f66f4

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 2, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.599dup p.S201* | Frame Shift Ins (INS) | VAF 25/102 reads (25%) | catalogued as rs768767517; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 17/48 reads (35%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GATA2 | c.1083_1085dup p.R362dup | In Frame Ins (INS) | VAF 14/95 reads (15%) | called by mutect2, pindel, varscan2
- MLLT3 | c.*220C>T | 3'UTR (SNP) | VAF 56/237 reads (24%) | catalogued as rs542807953; called by muse, varscan2
